Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VJ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VJ-01A (Primary Tumor).

[page 1 of 4]
Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right thyroid nodule papillary FNA-thyroid cancer.

Specimens Submitted:

- 1: Delphian nodes (fs)
- 2: Right para- tracheal lymph node (fs)
- 3: Pre-tracheal tissue midline (fs)
- 4: Rule out right lower para-thyroid gland (fs)
- 5: Total thyroidectomy
- 6: Right paratracheal tissue

DIAGNOSIS:

1. Delphian nodes (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma in the form of psammoma body
Number of lymph nodes examined: 1
Extranodal extension is not identified
The tumor was not present on the frozen section slide.

2. Right para- tracheal lymph node (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.19 cm.
Extranodal extension is not identified

ICD-O3

carcinoma, papillary,
diffuse sclerosing

8350/3

Site: thyroid, NOS

5-2-12
RD

CTB, G

3. Pre-tracheal tissue midline (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.7cm.
Size of the largest metastatic focus : 0.01 cm.
Extranodal extension is not identified

4. "Right lower para-thyroid gland", biopsy (fs):

- Benign unremarkable parathyroid gland tissue

5. Total thyroidectomy:

Tumor Type:

[page 2 of 4]
Papillary carcinoma, diffuse sclerosing variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe
Right lobe
Isthmus

Tumor Size:

The dominant tumor nodule is 2.0 cm in greatest dimension.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Extensive invasion

Extrathyroid Extension:

Invades fibroadipose tissue

Surgical Margins:

Free of tumor

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

6. "Right paratracheal tissue", excision:
- Benign unremarkable parathyroid gland

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section, labeled "Delphian node" and consists of one piece of tan-pink soft tissue measuring 0.9 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

[page 3 of 4]
2. The specimen is received fresh for frozen section, labeled "right paratracheal lymph node" and consists of two lymph nodes measuring 0.9 x 0.4 x 0.2 cm and 0.5 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3. The specimen is received fresh for frozen section, labeled "Pre-tracheal tissue - midline" and consists of one piece of tan-pink soft tissue measuring 1.5 x 1.0 x 0.6 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

4. The specimen is received fresh for frozen section, labeled "rule out right lower parathyroid gland" and consists of one piece of tan-pink soft tissue measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

5. The specimen is received fresh, labeled "total thymectomy, stitch marks right lobe" and consists of a thyroid weighing 36 g. The right lobe measures 6 x 4 x 2 cm, the left lobe measures 4 x 2 x 1.5 cm and the isthmus measures 1.3 x 0.5 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well circumscribed nodule measuring 1.8 x 1.5 x 1.0 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS, and a photograph has been taken. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N - nodule

RL - right lobe

LL - left lobe

IS - isthmus

6. The specimen is received fresh labeled, "right paratracheal tissue", and consists of multiple irregular pieces of tan soft tissue measuring 1.0 x 0.5 x 0.3 cm aggregate. Entirely submitted.

Summary of sections:

U-- undesignated

Summary of Sections:

Part 1: Delphian nodes (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right para- tracheal lymph node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Pre-tracheal tissue midline (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: Rule out right lower para-thyroid gland (fs)

Block	Sect. Site	PCs
1	FSC	1

[page 4 of 4]
Part 5: Total thyroidectomy

Block	Sect. Site	PCs
1	is	1
2	ll	2
3	n	3
2	rl	2

Part 6: Right paratracheal tissue

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Delphian nodes (fs): Benign lymph node
PERMANENT DIAGNOSIS: SEE FINAL
2. FROZEN SECTION DIAGNOSIS: Right para- tracheal lymph node (fs): 2 lymph nodes, both positive for metastatic PTC (2/2).
PERMANENT DIAGNOSIS: SAME
3. FROZEN SECTION DIAGNOSIS: Pre-tracheal tissue midline (fs): Metastatic PTC; definitely involving one lymph node. Second lymph node is cauterized with no definite tumor.
PERMANENT DIAGNOSIS: SAME
4. FROZEN SECTION DIAGNOSIS: Rule out right lower para-thyroid gland (fs): Parathyroid tissue.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 812a8c0d-c9de-4b14-840f-10516b5dfbed (TCGA-DJ-A3VJ.C8FBA360-6E43-4B3C-8D77-C0E57EB7937C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).